Somatic mutation profile of tumor specimen TCGA-TS-A7P3-01A (aliquot TCGA-TS-A7P3-01A-12D-A34C-32) from TCGA case TCGA-TS-A7P3, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 57.4 years (20,964 days).
Specimen TCGA-TS-A7P3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca90fa3f-a802-4193-a484-c750ac36649b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A7P3-10A (Blood Derived Normal), aliquot TCGA-TS-A7P3-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73c7a82b-ac74-4da5-87d0-1a4d5e36de82

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 10, Silent 8, Nonsense Mutation 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTCH1 | c.1603-2A>C p.X535_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as rs1064793921, CS146516; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMIE | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs28942097, CM022084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXO47 | c.795A>G p.G265= | Splice Region (SNP) | VAF 49/211 reads (23%) | catalogued as rs1275037581; called by muse, mutect2, varscan2
- FREM2 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV54852376; called by muse, mutect2, varscan2
- GON4L | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55202782; called by muse, mutect2, varscan2
- GZMM | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556484742, COSV99198840; called by muse, mutect2, varscan2
- HPS3 | c.2530G>A p.V844I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs758569835, COSV56054608; called by muse, varscan2
- SPTAN1 | c.6681C>A p.Y2227* | Nonsense Mutation (SNP) | VAF 20/83 reads (24%) | catalogued as rs1216906782; called by muse, mutect2, varscan2
- AP1G1 | c.2159C>G p.T720S | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORF4L2 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPCML | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- RSPH4A | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A4 | c.1240C>T p.Q414* (on ENST00000264485 / NM_001098484.3; = p.Q370* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2
- TRPM2 | c.117C>A p.S39R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCL7A | c.63C>T p.V21= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs1019086127; called by muse, mutect2, varscan2
- GOLGB1 | c.9717A>G p.L3239= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs960342533; called by muse, mutect2, varscan2
- KMT2A | c.3783T>A p.P1261= | Silent (SNP) | VAF 32/157 reads (20%) | called by muse, mutect2, varscan2
- NLRP8 | c.768C>T p.F256= | Silent (SNP) | VAF 27/164 reads (16%) | called by muse, mutect2, varscan2
- PRMT1 | c.324G>A p.K108= | Silent (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- RASGRF1 | c.2319C>T p.A773= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs147952942, COSV101174226; called by muse, mutect2, varscan2
- TGFB1I1 | c.1038C>T p.C346= (on ENST00000394863 / NM_001042454.3; = p.C329= on NM_015927.4) | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- TTN | c.59055T>C p.H19685= (on ENST00000591111; = p.H12261= on NM_003319.4) | Silent (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
